Somatic mutation profile of cancer-model specimen HCM-BROD-0711-C64-85B (3D Organoid, passage 12; aliquot HCM-BROD-0711-C64-85B-01D-A881-36), derived from the primary tumor of HCMI case HCM-BROD-0711-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 63.8 years (23,306 days).
Specimen HCM-BROD-0711-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5efe8468-806c-4792-b7ef-367bdc844a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0711-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0711-C64-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1aa3390-e71a-4122-bad6-98d90db6d9c3

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY7 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 258/890 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs150835400; called by muse, mutect2, varscan2
- COL9A3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 42/872 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs551439892; called by muse, mutect2
- LRRC72 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 187/619 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.072); catalogued as rs886746919; called by muse, mutect2, varscan2
- ZNF521 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 106/485 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs140546909; called by muse, mutect2, varscan2
- CDKN1A | c.248_262delinsC p.R83Pfs*41 | Frame Shift Del (DEL) | VAF 189/504 reads (38%) | called by pindel, varscan2*
- CHD4 | c.3678_3689del p.K1226_D1230delinsN (on ENST00000357008 / NM_001363606.2; = p.K1239_D1243delinsN on NM_001273.5) | In Frame Del (DEL) | VAF 72/302 reads (24%) | called by mutect2, pindel, varscan2
- EDN3 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 121/405 reads (30%) | called by muse, mutect2, varscan2
- GRHL2 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VSIR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 158/564 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCAF16 | c.447C>T p.T149= | Silent (SNP) | VAF 125/542 reads (23%) | called by muse, mutect2, varscan2
- UBASH3A | c.1347C>T p.N449= | Silent (SNP) | VAF 34/428 reads (8%) | catalogued as rs374847418; called by muse, mutect2
- ZNF724 | c.1767C>A p.P589= | Silent (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
